Gene-level copy-number profile of tumor specimen TCGA-CV-7414-01A from TCGA case TCGA-CV-7414, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 78.3 years (28,603 days).
Specimen TCGA-CV-7414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.65f76f36-5979-4d92-8129-76e9406aec1d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7414-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a7cdb15e-db4e-446e-a6cc-b874f0a5afa8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 13,511; copy number 2: 38,322; copy number 3: 7,010; copy number 4: 353; copy number 5: 150; copy number 6: 85; copy number 7: 236; copy number 9: 25; copy number 11: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7414-01A-11D-2077-01): tumor purity 0.82, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:179,678,628–179,731,641, 1 gene (within-gene range 0–1): CANX.
- chr5:179,732,822–179,838,078, 5 genes (within-gene range 0–1): MAML1, LTC4S, MGAT4B, MIR1229, SQSTM1.
- chr10:87,859,158–89,414,557, 34 genes (within-gene range 0–1): KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 566 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:97,025,981–97,589,965, 25 genes, copy number 9 (within-gene range 3–9): TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B, AC018892.3, RN7SL313P, ANKRD36, AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1.
- chr4:114,827,763–117,360,655, 23 genes, copy number 6–7 (within-gene range 2–7): NDST4, MRPS33P3, RPF2P2, PGAM4P2, KRT18P21, AC027613.1, EIF3KP3, TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1, ACTN4P1, AC093765.5, AC093765.4, AC093765.3, AC093765.2, RNU6-119P, AC093765.1, TRAM1L1, AC107399.1, LINC02262.
- chr7:93,424,486–94,712,511, 26 genes, copy number 7: CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P.
- chr7:100,867,387–103,989,658, 103 genes, copy number 7 (within-gene range 2–15) (broad region; genes not listed).
- chr7:106,624,072–107,564,261, 11 genes, copy number 5 (within-gene range 2–5): AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1.
- chr8:36,378,069–38,853,028, 67 genes, copy number 6 (broad region; genes not listed).
- chr11:69,147,228–71,997,597, 85 genes, copy number 6–11 (within-gene range 2–11) (broad region; genes not listed).
- chr13:109,163,902–114,223,084, 111 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:30,897,336–31,382,116, 18 genes, copy number 5 (within-gene range 3–5): TEFM, AC130324.3, ADAP2, AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1.
- chr17:32,492,522–32,877,177, 1 gene, copy number 5 (within-gene range 4–5): MYO1D.
- chr17:32,627,739–32,997,877, 6 genes, copy number 5 (within-gene range 4–5): AC025211.1, Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3.
- chr17:33,052,107–33,131,743, 3 genes, copy number 5: AC003687.1, AC008133.2, AC008133.1.
- chr17:38,671,703–40,304,657, 86 genes, copy number 7 (broad region; genes not listed).
- chr17:40,317,698–40,318,676, 1 gene, copy number 7: AC080112.4.

Autosomal genes at a single copy (total copy number 1): 11,095. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
